Gene-level copy-number profile of tumor specimen TCGA-85-8481-01A from TCGA case TCGA-85-8481, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 70.6 years (25,782 days).
Specimen TCGA-85-8481-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.a31697f3-7968-4911-ae50-c992e9614313.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8481-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 407 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/687d696e-208f-4b9c-bc97-cf372b43b3c6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,731; copy number 1: 12,435; copy number 2: 37,085; copy number 3: 4,898; copy number 4: 2,617; copy number 5: 386; copy number 6: 20; copy number 7: 2; copy number 12: 1; copy number 19: 11; copy number 31: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8481-01A-11D-2322-01): tumor purity 0.29, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 348 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr1:210,859,177–210,862,285, 1 gene: IPO8P1.
- chr4:166,388,701–190,092,279, 324 genes (within-gene range 0–1) (broad region; genes not listed).
- chr5:77,942,757–78,986,087, 15 genes: AC108482.1, AC108482.2, AP3B1, AC024568.1, ATP6V1G1P6, AC104108.1, RNU6-183P, Y_RNA, SCAMP1-AS1, SCAMP1, LHFPL2, HMGB1P21, AC008802.1, AC025755.1, ARSB.
- chr5:79,000,112–79,001,124, 1 gene: AC020937.1.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr15:24,101,827–24,823,365, 5 genes (within-gene range 0–3): PWRN1, PWRN2, AC087463.1, AC087463.2, AC087463.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 450 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:238,842,767–238,848,115, 1 gene, copy number 12: AL583825.1.
- chr3:162,486,541–185,052,614, 346 genes, copy number 5 (broad region; genes not listed).
- chr8:97,624,203–98,294,393, 19 genes, copy number 5: AP002982.1, AP002982.2, MTDH, Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P.
- chr11:13,276,652–17,207,983, 60 genes, copy number 6–31: ARNTL, RN7SKP151, BTBD10, AC021269.3, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3, CYP2R1, CALCB, CALCP, CALCA, OR7E41P, INSC, AC104361.1, LINC02751, AC073172.1, AC087379.2, AC087379.1, AC009869.1, LINC02682, SOX6, MIR6073, AC103794.1, AKR1B1P3, RN7SL188P, C11orf58, PLEKHA7, RN7SKP90, AC116533.1, OR7E14P, RPS13, SNORD14A, SNORD14B, PIK3C2A, RNU6-593P, AC126389.1, AC107956.2.
- chr11:17,228,279–17,229,151, 1 gene, copy number 6: AC107956.1.
- chr11:108,665,069–108,940,927, 1 gene, copy number 7 (within-gene range 2–7): DDX10.
- chr11:108,822,333–108,822,650, 1 gene, copy number 7: CYCSP29.
- chr12:132,550,729–132,761,832, 14 genes, copy number 5 (within-gene range 2–5): AC131212.3, AC131212.2, MIR6763, AC131212.1, LRCOL1, P2RX2, AC131212.4, POLE, PXMP2, AC135586.2, PGAM5, RNA5SP379, ANKLE2, AC135586.1.
- chr19:47,745,546–47,819,051, 7 genes, copy number 5: NOP53, SNORD23, NOP53-AS1, SELENOW, RPL23AP80, AC008745.1, TPRX1.

Autosomal genes at a single copy (total copy number 1): 12,429. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
